MMRF case MMRF_2847 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/cfcf4521-d340-4526-b77b-91954c582d45

Demographics
Sex at birth: male; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.7 years (21,063 days); ISS stage: III; Days to last known disease status: 163 days; Days to last follow up: 163 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -4, day 163.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Beta 2 Microglobulin 6.59 µg/mL.
- Albumin 34.9 g/L.
- Hemoglobin 5.77 mmol/L.
- Creatinine 76.9 µmol/L.
- Lactate Dehydrogenase 3.08 µkat/L.
- Calcium 1.95 mmol/L.
- Platelets 199 ×10⁹/L.
- M Protein 5.38 g/dL.
- Absolute Neutrophil 6.39 ×10⁹/L.

Other clinical attributes
- Day -4: Weight: 73 kg; Height: 180 cm.

Biospecimens (2 samples)
- Sample MMRF_2847_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_2847_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
